Somatic mutation profile of tumor specimen TARGET-20-PANSJB-09A (aliquot TARGET-20-PANSJB-09A-01D) from TARGET case TARGET-20-PANSJB, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,074 days).
Specimen TARGET-20-PANSJB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ead73da-07e7-4a94-827a-39db418a9c95.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANSJB-14A (Bone Marrow Normal), aliquot TARGET-20-PANSJB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f36eef64-8b05-4de4-b315-8d1d469049db

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND3 | c.826_827insGA p.Q276Rfs*29 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | catalogued as COSV57828565; called by mutect2, pindel, varscan2
- TET2 | c.2749C>T p.Q917* | Nonsense Mutation (SNP) | VAF 235/253 reads (93%) | catalogued as COSV54412437; called by muse, mutect2, varscan2
